TCGA case TCGA-13-1495 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/74dcdfb4-a637-4111-9a22-4b4bc7bbc8f7

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 60 years; Vital status: Dead; Days to death: 2,749 days (7.5 years).

Diagnoses (3)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 60.4 years (22,046 days); Year of diagnosis: 2004; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 140 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 119 days; Treatment dose: 250 mg/m2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 21 days; Days to treatment end: 140 days; Number of cycles: 6; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Cetuximab; Treatment intent type: Adjuvant; Days to treatment start: 147 days; Days to treatment end: 224 days; Treatment dose: 250 mg/m2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 231 days; Days to treatment end: 548 days (1.5 years); Number of cycles: 12; Treatment dose: 175 mg/m2; Route of administration: Intravenous.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 63.0 years (23,023 days); Days to diagnosis: 977 days (2.7 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 984 days (2.7 years).
3. Diagnosis record without a diagnosis name: Tumor of origin: diagnosis 1 of this record; Age at diagnosis: 63.0 years (23,023 days); Days to diagnosis: 977 days (2.7 years); Prior treatment: Yes.

Follow-up (5 entries)
- Day 977 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 977 days (2.7 years); Evidence of recurrence type: Convincing Image Source.
- Days to follow up: 1,498 days (4.1 years); Disease response: With Tumor.
- Progression or recurrence: Yes; Progression or recurrence type: Distant; Evidence of progression type: Convincing Image Source; Timepoint: Post Initial Treatment.
- Karnofsky performance status: 80; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contact recording only the day: day 2,749.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-13-1495-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 2.1; Intermediate dimension: 1.5; Shortest dimension: 0.4.
  Slide TCGA-13-1495-01A-01-BS1: Section location: Bottom; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20.
  Slide TCGA-13-1495-01A-01-TS1: Section location: Top; Percent tumor cells: 79; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 20.
- Sample TCGA-13-1495-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; Tumor status: With tumor; Performance status timing: Pre-Adjuvant Therapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 2,749 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 2,749 days; disease-free interval: event (new tumor event after initially disease-free), 977 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 977 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-13-1495-01A-01D-0472-01): tumor purity 0.82, ploidy 3.82, whole-genome doublings 1.
